Somatic mutation profile of tumor specimen TCGA-CN-6024-01A (aliquot TCGA-CN-6024-01A-11D-1683-08) from TCGA case TCGA-CN-6024, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 66.4 years (24,259 days).
Specimen TCGA-CN-6024-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e08f61d-86d8-40a9-a4c7-0281ae07caa2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-6024-10A (Blood Derived Normal), aliquot TCGA-CN-6024-10A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6077463-ff5c-45f6-84cd-be564a2138a7

The open-access MAF lists 189 somatic variants for this specimen: 122 protein-altering or splice-affecting, 64 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 64, Nonsense Mutation 6, Frame Shift Del 4, Splice Region 3, 5'Flank 2, Splice Site 2, In Frame Del 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 29/60 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.794T>G p.L265R | Missense Mutation (SNP) | VAF 16/24 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD004355, CM971505, COSV52706540, COSV52732531, COSV53696163; called by muse, mutect2, varscan2
- ABCC8 | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as rs775776658, CM110313, COSV56856460; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACOT2 | c.353C>T p.T118I | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs531121405, COSV99468988; called by muse, mutect2, varscan2
- ALDH9A1 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100699298; called by muse, mutect2, varscan2
- AMPH | c.344A>G p.D115G | Missense Mutation (SNP) | VAF 48/242 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1459949553, COSV100341843; called by muse, mutect2, varscan2
- APAF1 | c.1340A>G p.E447G (on ENST00000551964 / NM_181861.2; = p.E436G on NM_001160.3) | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1180490017, COSV100452480; called by muse, mutect2, varscan2
- ASB12 | c.344G>C p.S115T | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.894); catalogued as COSV100744701; called by muse, varscan2
- ATM | c.712A>G p.I238V | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs754275014, COSV99589390; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ATM | c.3103A>G p.I1035V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV53784956; called by muse, mutect2, varscan2
- ATP6V0D2 | c.884A>G p.E295G | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as COSV99571635; called by muse, mutect2, varscan2
- AXIN2 | c.1898A>T p.K633M | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV100196418; called by muse, mutect2, varscan2
- BDH2 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99600666; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2042A>T p.D681V | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV100863735; called by muse, mutect2, varscan2
- BMP5 | c.1310A>T p.N437I | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100895950; called by muse, mutect2, varscan2
- C9orf43 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99928315; called by muse, mutect2, varscan2
- CADPS2 | c.2266G>C p.E756Q | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV100462501, COSV57393421; called by muse, mutect2
- CCDC141 | c.2171G>A p.R724Q | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1429178522, COSV55373924; called by muse, mutect2, varscan2
- CCDC88B | c.2698C>T p.L900F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs1053582699, COSV100105349; called by muse, mutect2
- CCNJL | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99979445; called by muse, mutect2, varscan2
- CDH6 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99418966; called by muse, mutect2, varscan2
- CDK8 | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 76/137 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs993713272, COSV101037165; called by muse, mutect2, varscan2
- CERT1 | c.824C>G p.S275C (on ENST00000405807 / NM_001130105.1; = p.S147C on NM_005713.3) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99783183; called by muse, mutect2, varscan2
- CIAO1 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99302587; called by muse, mutect2, varscan2
- CLCA4 | c.2121C>T p.N707= | Splice Region (SNP) | VAF 4/11 reads (36%) | catalogued as rs775219259, COSV99760453; called by muse, mutect2, varscan2
- CNTN1 | c.31G>T p.V11L | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100751306; called by muse, mutect2, varscan2
- COL4A6 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 44/51 reads (86%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100564010; called by muse, mutect2, varscan2
- COL6A6 | c.3241G>T p.A1081S | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as COSV100650197; called by muse, mutect2, varscan2
- CORIN | c.1553G>A p.C518Y | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779393074, COSV99903503; called by muse, mutect2, varscan2
- CTNND2 | c.233G>A p.S78N | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100475828; called by muse, mutect2, varscan2
- CTTNBP2 | c.4811T>A p.L1604* | Nonsense Mutation (SNP) | VAF 62/121 reads (51%) | catalogued as COSV99353782; called by muse, mutect2, varscan2
- CYP4Z1 | c.1511T>C p.V504A | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV100497644; called by muse, mutect2, varscan2
- DIAPH1 | c.3116A>T p.D1039V | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99526447; called by muse, mutect2, varscan2
- DMD | c.9442del p.L3148Cfs*7 | Frame Shift Del (DEL) | VAF 19/35 reads (54%) | catalogued as COSV100630108; called by mutect2, pindel, varscan2
- DNAAF2 | c.443C>A p.P148Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV100023981; called by muse, mutect2, varscan2
- DTNA | c.1284C>A p.N428K | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99312467; called by muse, mutect2, varscan2
- EMILIN1 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs1221738236, COSV100980218; called by muse, mutect2
- ERBB4 | c.3184A>C p.N1062H | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1553519043, COSV100725349; called by muse, mutect2, varscan2
- FMO3 | c.1215G>A p.M405I | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as CD085185, COSV100882435; called by muse, mutect2, varscan2
- FOLH1 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99923138; called by muse, mutect2, varscan2
- GRID1 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.757); catalogued as COSV100023741; called by muse, mutect2, varscan2
- IL1RAPL2 | c.689A>C p.K230T | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.629); catalogued as COSV100781218; called by muse, mutect2, varscan2
- IQGAP2 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.621); catalogued as rs572815114, COSV99167125; called by muse, mutect2, varscan2
- ITPR2 | c.1755T>G p.I585M | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101189956; called by muse, mutect2
- ITSN2 | c.1460A>G p.K487R | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs763336031, COSV100743318; called by muse, mutect2, varscan2
- KCNH4 | c.1247C>T p.S416L | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs773634955, COSV99237096; called by muse, mutect2, varscan2
- KCNV1 | c.893G>T p.S298I | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.292); catalogued as COSV99819051; called by muse, mutect2, varscan2
- KIRREL1 | c.1963C>T p.R655W | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1166442522, COSV100779835; called by muse, mutect2, varscan2
- KREMEN1 | c.107A>G p.N36S (on ENST00000407188; = p.N38S on NM_032045.5) | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs35199515; called by muse, mutect2, varscan2
- KRTAP15-1 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV100481622; called by muse, mutect2, varscan2
- LCOR | c.2987A>G p.N996S | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99616831; called by muse, mutect2, varscan2
- LGALS3BP | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV99431603; called by muse, varscan2
- LRP1B | c.8186C>T p.A2729V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1377724782, COSV101256083; called by muse, mutect2, varscan2
- MAP4K1 | c.650A>T p.D217V | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101204211; called by muse, mutect2, varscan2
- ME3 | c.767A>C p.Y256S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100042225; called by muse, mutect2, varscan2
- MIEF1 | c.358A>T p.R120W | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.29); catalogued as COSV100307650; called by muse, mutect2, varscan2
- MROH2B | c.4115T>C p.I1372T | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV68181770; called by muse, mutect2, varscan2
- MRPS25 | c.161A>T p.Q54L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV99507712; called by muse, mutect2, varscan2
- NEB | c.15527C>A p.P5176H | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99421397; called by muse, mutect2, varscan2
- NGFR | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as rs1184219372, COSV50801778; called by muse, mutect2, varscan2
- NXPE3 | c.1043C>G p.T348R | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV99839922; called by muse, mutect2, varscan2
- ONECUT1 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV100009166; called by muse, mutect2, varscan2
- OR4A16 | c.599A>G p.N200S | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.536); catalogued as rs756663590, COSV100125182; called by muse, mutect2, varscan2
- OR7D4 | c.592G>T p.V198F | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV100432707, COSV100432899; called by muse, mutect2, varscan2
- OTUB2 | c.304-1G>A p.X102_splice | Splice Site (SNP) | VAF 12/45 reads (27%) | catalogued as rs1285492579, COSV99180145, COSV99180154, COSV99180159; called by muse, mutect2, varscan2
- PAPPA2 | c.4978C>A p.L1660M | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as COSV62791720, COSV62810673; called by muse, mutect2, varscan2
- PCDH10 | c.2861G>A p.W954* | Nonsense Mutation (SNP) | VAF 37/67 reads (55%) | catalogued as COSV99993459; called by muse, mutect2, varscan2
- PCDH12 | c.1333C>T p.Q445* | Nonsense Mutation (SNP) | VAF 36/115 reads (31%) | catalogued as COSV99187825; called by muse, mutect2, varscan2
- PCDHA7 | c.1127A>T p.D376V | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100971450; called by muse, varscan2
- PCDHB6 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs781940602, COSV50691167; called by muse, mutect2, varscan2
- PDE10A | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV63100518; called by muse, mutect2, varscan2
- PGLYRP2 | c.1561G>T p.G521C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99483969; called by muse, mutect2, varscan2
- PIK3R5 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV52655190, COSV99036456; called by muse, mutect2
- PON1 | c.848G>C p.G283A | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.616); catalogued as COSV99732211; called by muse, mutect2, varscan2
- PRDM9 | c.1652T>A p.L551H | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV57011046, COSV99690350; called by muse, mutect2, varscan2
- PRTG | c.1718C>T p.T573M | Missense Mutation (SNP) | VAF 41/64 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs373191733; called by muse, mutect2, varscan2
- PRUNE2 | c.3757C>A p.P1253T | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100944503; called by muse, mutect2, varscan2
- PTPN21 | c.2198G>T p.R733L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV100161558, COSV100161857; called by muse, mutect2
- PTPN23 | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780485797, COSV99650525; called by muse, mutect2, varscan2
- RASSF9 | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 112/183 reads (61%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.509); catalogued as COSV100771346, COSV63433668; called by muse, mutect2, varscan2
- RFFL | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs758936328, COSV99265286; called by muse, mutect2, varscan2
- RNF130 | c.554T>A p.M185K | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99992661; called by muse, varscan2
- RP1 | c.5543C>A p.A1848E | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV99607265; called by muse, mutect2, varscan2
- RYR3 | c.6818A>T p.E2273V (on ENST00000389232; = p.E2274V on NM_001036.6) | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV100774393; called by muse, mutect2, varscan2
- S1PR1 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV59513241; called by muse, mutect2, varscan2
- SBF2 | c.2204T>A p.L735Q | Missense Mutation (SNP) | VAF 63/234 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99814057; called by muse, mutect2, varscan2
- SESTD1 | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV101468093; called by muse, mutect2, varscan2
- SIAH2 | c.613T>A p.F205I | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100469227, COSV57262938; called by muse, mutect2, varscan2
- SLC12A3 | c.1486G>A p.G496S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.98); catalogued as rs777612082, CM961291, COSV99343912; called by muse, varscan2
- SLC44A2 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100213170; called by muse, mutect2, varscan2
- SLC5A8 | c.53T>A p.F18Y | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101610548; called by muse, mutect2, varscan2
- SLC9A4 | c.1459G>T p.E487* | Nonsense Mutation (SNP) | VAF 19/84 reads (23%) | catalogued as COSV99762970; called by muse, mutect2, varscan2
- SMG8 | c.2876C>G p.A959G | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as COSV99958796; called by muse, mutect2, varscan2
- SOGA3 | c.2266G>A p.D756N | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100846897; called by muse, mutect2, varscan2
- SSC4D | c.1376A>T p.E459V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.654); catalogued as COSV99299934; called by mutect2, varscan2
- SYCP2L | c.806G>C p.R269P | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.619); catalogued as COSV99305095; called by muse, mutect2, varscan2
- SYNE2 | c.18938A>G p.K6313R | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100647490; called by muse, mutect2, varscan2
- TACC2 | c.5835G>A p.R1945= (on ENST00000334433; = p.M23I on NM_006997.4) | Splice Region (SNP) | VAF 40/147 reads (27%) | catalogued as COSV99587021; called by muse, mutect2, varscan2
- TAFA4 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs867966396, COSV99806914; called by muse, mutect2, varscan2
- TEKT3 | c.663G>T p.T221= | Splice Region (SNP) | VAF 137/219 reads (63%) | catalogued as COSV100107011; called by muse, mutect2, varscan2
- TG | c.202C>A p.R68S | Missense Mutation (SNP) | VAF 65/113 reads (58%) | SIFT tolerated (0.72); PolyPhen benign (0.209); catalogued as COSV55076042, COSV99600537, COSV99603652; called by muse, mutect2, varscan2
- TPST2 | c.455C>G p.A152G | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100114057; called by muse, mutect2, varscan2
- TRIM16 | c.1526A>G p.Y509C | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766944647, COSV100371850; called by muse, mutect2, varscan2
- TTC21B | c.2201A>G p.N734S | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.054); catalogued as COSV99692217; called by muse, mutect2, varscan2
- TTN | c.21280A>G p.R7094G (on ENST00000591111; = p.R6167G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | PolyPhen benign (0.033); catalogued as rs780911294, COSV100610283; called by muse, mutect2, varscan2
- WDR70 | c.1015A>T p.T339S | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.158); catalogued as rs1178675399, COSV99458621; called by muse, mutect2, varscan2
- ZBTB46 | c.1570C>G p.P524A | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV99829087; called by muse, mutect2, varscan2
- ZC3H7B | c.2927G>T p.G976V | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as COSV100687313; called by muse, mutect2, varscan2
- ZFAT | c.3284C>T p.T1095I | Missense Mutation (SNP) | VAF 39/301 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.348); catalogued as COSV100914529; called by muse, mutect2, varscan2
- ZGRF1 | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT tolerated (0.08); PolyPhen benign (0.121); catalogued as COSV100005494; called by muse, mutect2, varscan2
- ZNF180 | c.1407A>T p.Q469H | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.516); catalogued as COSV55423319, COSV99659802; called by muse, mutect2, varscan2
- ZNF420 | c.584A>G p.Y195C | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100421315; called by muse, mutect2, varscan2
- ZNF479 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1554400022, COSV58645442; called by muse, mutect2, varscan2
- ZNF71 | c.1333A>T p.K445* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as COSV100045855; called by muse, mutect2, varscan2
- ZNF799 | c.1823A>T p.K608M | Missense Mutation (SNP) | VAF 66/203 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV101345255; called by muse, varscan2
- ZNF829 | c.224-2A>G p.X75_splice | Splice Site (SNP) | VAF 11/44 reads (25%) | catalogued as COSV101199642; called by muse, mutect2, varscan2
- ZNF93 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.733); catalogued as COSV100652268; called by muse, mutect2, varscan2
- CDH1 | c.1174_1179del p.V392_I393del | In Frame Del (DEL) | VAF 21/77 reads (27%) | called by mutect2, pindel, varscan2
- CHD3 | c.1171dup p.I391Nfs*5 | Frame Shift Ins (INS) | VAF 27/83 reads (33%) | called by mutect2, pindel, varscan2
- FAT1 | c.9688_9691del p.F3230Sfs*39 | Frame Shift Del (DEL) | VAF 22/35 reads (63%) | called by mutect2, pindel, varscan2
- MAST2 | c.443_444del p.S148Cfs*24 | Frame Shift Del (DEL) | VAF 34/72 reads (47%) | called by mutect2, pindel, varscan2
- TMEM200C | c.1739_1748del p.Q580Pfs*21 | Frame Shift Del (DEL) | VAF 10/85 reads (12%) | called by mutect2, pindel, varscan2
- AC004922.1 | c.36C>T p.T12= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV99501113; called by muse, mutect2, varscan2
- ADAMTSL5 | c.1401G>A p.R467= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV100389150; called by muse, mutect2, varscan2
- AHCTF1 | c.2283T>C p.D761= (on ENST00000366508; = p.D735= on NM_015446.5) | Silent (SNP) | VAF 36/66 reads (55%) | catalogued as COSV100403568; called by muse, mutect2, varscan2
- AKT3 | c.585T>G p.T195= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV99795227; called by muse, mutect2, varscan2
- ANAPC1 | c.4902A>G p.L1634= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100594677; called by mutect2, varscan2
- ARL6 | c.309T>A p.V103= | Silent (SNP) | VAF 35/62 reads (56%) | catalogued as COSV100256461; called by muse, mutect2, varscan2
- ARNTL2 | c.378G>A p.L126= | Silent (SNP) | VAF 18/160 reads (11%) | catalogued as rs771686261, COSV99667709; called by muse, mutect2, varscan2
- BSX | c.480C>T p.N160= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV100545227; called by muse, mutect2, varscan2
- C11orf53 | c.420G>A p.P140= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV54721551; called by muse, mutect2, varscan2
- CACNA1I | c.3651C>T p.G1217= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs745600843, COSV100360066, COSV60807660; called by mutect2, varscan2
- CD38 | c.579C>A p.S193= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV56888849; called by muse, varscan2
- CDC20 | c.171C>T p.G57= | Silent (SNP) | VAF 21/32 reads (66%) | catalogued as rs748677941, COSV100196440; called by muse, mutect2, varscan2
- CFAP46 | c.6768A>G p.E2256= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99584601; called by muse, mutect2, varscan2
- CYP7A1 | c.120A>G p.P40= | Silent (SNP) | VAF 79/304 reads (26%) | catalogued as rs759284212, COSV100052337; called by muse, mutect2, varscan2
- DCLRE1C | c.1125G>T p.L375= (on ENST00000378278 / NM_001350965.2; = p.L260= on NM_022487.4) | Silent (SNP) | VAF 43/137 reads (31%) | catalogued as COSV100739798; called by muse, mutect2, varscan2
- DDX55 | c.1569G>A p.K523= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV99434496; called by muse, mutect2, varscan2
- DPYD | c.633C>T p.Y211= | Silent (SNP) | VAF 78/122 reads (64%) | catalogued as COSV64591253; called by muse, mutect2, varscan2
- ELF5 | c.636A>T p.A212= (on ENST00000312319 / NM_198381.2; = p.A202= on NM_001422.4) | Silent (SNP) | VAF 56/128 reads (44%) | catalogued as COSV99141200; called by muse, mutect2, varscan2
- ERICH3 | c.1359A>T p.S453= | Silent (SNP) | VAF 97/149 reads (65%) | catalogued as COSV100444170; called by muse, mutect2, varscan2
- EXOC2 | c.1941A>G p.Q647= | Silent (SNP) | VAF 39/83 reads (47%) | catalogued as rs1417414225, COSV100033497; called by muse, mutect2, varscan2
- FBXO30 | c.13C>T p.L5= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99395176; called by muse, mutect2
- GDF5 | c.1245C>T p.D415= | Silent (SNP) | VAF 131/193 reads (68%) | catalogued as rs777837831, COSV65503514; called by muse, mutect2, varscan2
- GSDMC | c.735C>T p.S245= | Silent (SNP) | VAF 15/111 reads (14%) | catalogued as rs765277111, COSV52699751; called by muse, mutect2, varscan2
- HECTD1 | c.6201A>G p.L2067= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV101237361; called by muse, mutect2, varscan2
- HP | c.1080C>T p.A360= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as rs531798346, COSV63326399; called by muse, mutect2, varscan2
- IFT172 | c.468G>A p.V156= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs1249420741, COSV99562402; called by muse, mutect2, varscan2
- IL16 | c.1800A>T p.P600= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100267473; called by muse, mutect2, varscan2
- ITGB4 | c.4626A>C p.T1542= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV99563942; called by muse, mutect2, varscan2
- LAMP5 | c.576T>C p.S192= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV99855555; called by muse, mutect2, varscan2
- LARS1 | c.2892A>T p.G964= (on ENST00000394434 / NM_020117.11; = p.G937= on NM_016460.3) | Silent (SNP) | VAF 31/40 reads (78%) | catalogued as COSV99198582; called by muse, mutect2, varscan2
- LRRC4C | c.526C>A p.R176= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as COSV53419648, COSV99538016; called by muse, mutect2, varscan2
- MAP3K5 | c.1608A>G p.Q536= | Silent (SNP) | VAF 49/149 reads (33%) | catalogued as COSV100752750, COSV62889157; called by muse, mutect2, varscan2
- MIOS | c.1854A>G p.A618= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as COSV100402711; called by muse, mutect2, varscan2
- MUC16 | c.29208G>T p.T9736= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV101199665; called by muse, mutect2, varscan2
- MYH4 | c.1833G>T p.L611= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as rs577534095, COSV99701111; called by muse, mutect2, varscan2
- MYH8 | c.3394C>A p.R1132= | Silent (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- MYO10 | c.51C>A p.G17= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV101549861; called by muse, mutect2, varscan2
- NCK2 | c.420C>T p.V140= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as rs1178351596, COSV99255672; called by muse, mutect2, varscan2
- OR13F1 | c.861T>C p.P287= | Silent (SNP) | VAF 43/49 reads (88%) | catalogued as rs1461606291, COSV100594745; called by muse, mutect2, varscan2
- PARL | c.1119A>G p.K373= | Silent (SNP) | VAF 74/290 reads (26%) | catalogued as COSV100226187; called by muse, mutect2, varscan2
- PCDHA7 | c.1176C>T p.R392= | Silent (SNP) | VAF 26/120 reads (22%) | catalogued as COSV65348024; called by muse, varscan2
- PLD1 | c.2052A>C p.A684= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100578077; called by muse, mutect2, varscan2
- POFUT2 | c.1143T>C p.F381= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV100499227; called by muse, mutect2, varscan2
- PRDM9 | c.1653C>T p.L551= | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as rs1197521846, COSV99690352; called by muse, mutect2, varscan2
- PRKCG | c.867G>A p.P289= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs139506301, COSV54728640; called by muse, mutect2, varscan2
- PRPF40B | c.627C>T p.T209= (on ENST00000380281; = p.T203= on NM_012272.3) | Silent (SNP) | VAF 55/78 reads (71%) | catalogued as COSV99979745; called by muse, mutect2, varscan2
- RAD54L | c.1623C>T p.V541= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV100586304; called by muse, varscan2
- RB1 | c.1263T>C p.D421= | Silent (SNP) | VAF 30/47 reads (64%) | catalogued as COSV99924468; called by muse, mutect2, varscan2
- RBM26 | c.501C>T p.D167= | Silent (SNP) | VAF 58/93 reads (62%) | catalogued as rs778985440, COSV99936089; called by muse, mutect2, varscan2
- RBMS1 | c.126C>A p.T42= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV100816828; called by muse, mutect2, varscan2
- RNF31 | c.2256C>G p.L752= | Silent (SNP) | VAF 45/85 reads (53%) | catalogued as COSV100141793; called by muse, mutect2, varscan2
- RS1 | c.633C>T p.A211= | Silent (SNP) | VAF 39/50 reads (78%) | catalogued as COSV101183795; called by muse, mutect2, varscan2
- RXFP3 | c.921G>A p.A307= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs767585359, COSV57503839; called by muse, mutect2
- SLCO5A1 | c.426G>A p.A142= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV52656543; called by muse, mutect2, varscan2
- SLITRK3 | c.1368C>A p.P456= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV99579121; called by muse, mutect2, varscan2
- SPTBN2 | c.3726C>A p.G1242= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV100019155; called by muse, mutect2, varscan2
- TBPL2 | c.318T>C p.V106= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV99905388; called by muse, mutect2, varscan2
- TRMT61B | c.279G>A p.L93= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV100066547; called by muse, mutect2, varscan2
- TRPM3 | c.1113G>A p.S371= (on ENST00000357533 / NM_001366142.2; = p.S216= on NM_020952.6) | Silent (SNP) | VAF 34/56 reads (61%) | catalogued as rs372294629; called by muse, mutect2, varscan2
- UBQLN3 | c.309A>C p.P103= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100293603, COSV61164728; called by muse, mutect2, varscan2
- UNC13A | c.3699A>T p.A1233= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99408086; called by muse, mutect2, varscan2
- UROC1 | c.1116T>A p.P372= | Silent (SNP) | VAF 33/160 reads (21%) | catalogued as COSV99331345; called by muse, mutect2, varscan2
- VPS13B | c.7464G>A p.L2488= | Silent (SNP) | VAF 93/356 reads (26%) | catalogued as COSV100661838; called by muse, mutect2, varscan2
- ZER1 | c.591G>A p.P197= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as rs767172849, COSV99402035; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847129 A>G | 5'Flank (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- MIR1270 | chr19:20397831 G>A | 3'Flank (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- ZNF467 | chr7:149777739 C>T | 5'Flank (SNP) | VAF 14/30 reads (47%) | catalogued as COSV100022443; called by muse, mutect2, varscan2
